Gene-level copy-number profile of tumor specimen HTMCP-03-06-02182-01C from CGCI case HTMCP-03-06-02182, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenosquamous carcinoma; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02182-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 66b6591d-000c-4a30-82f6-4c4caaf52174.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02182-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/cc49a546-ff5f-4c34-8722-8b3f7b879d81

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 10,071; copy number 2: 40,852; copy number 3: 6,726; copy number 4: 464; copy number 5: 254.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–1): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr4:131,720,260–131,720,543, 1 gene: RN7SL205P.
- chr5:69,875,271–70,555,266, 15 genes: GUSBP13, AC131392.1, CDH12P2, SERF1B, SMN2, AC140134.1, NAIPP2, CDH12P3, AC138866.1, GUSBP14, GTF2H2B, AC146944.2, NAIPP1, AC146944.1, GUSBP15.
- chr5:70,968,166–71,025,339, 1 gene: NAIP.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 254 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:795,606–1,225,111, 14 genes, copy number 5: ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19.
- chr5:31,093,977–45,895,970, 240 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,071. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
